Gene-level copy-number profile of tumor specimen C3L-06940-01 from CPTAC case C3L-06940, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 69.3 years (25,321 days).
Specimen C3L-06940-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0737d876-9e17-4d37-baa8-abb1822424b1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06940-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/c563714f-5586-4dfa-bafa-8d384b9b778c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 518; copy number 1: 6,806; copy number 2: 45,133; copy number 3: 6,333; copy number 4: 52; copy number 5: 66.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes (within-gene range 0–2): AC104164.2, MIR548BB.
- chr6:1,623,806–2,245,605, 2 genes: GMDS, AL035693.1.
- chr9:9,442,060–9,442,380, 1 gene (within-gene range 0–2): RN7SL5P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 66 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:112,177,234–114,995,370, 66 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,463. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
